Gene-level copy-number profile of tumor specimen ALCH-AEKQ-TTP1-A from ALCHEMIST case ALCH-AEKQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-AEKQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 408cda16-ef62-48ad-8b93-5a116776cf9e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/bc4a7311-da48-496f-8fbf-d9a0fafaf6b0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 27; copy number 2: 14,814; copy number 3: 23,172; copy number 4: 10,401; copy number 5: 8,150; copy number 6: 1,010; copy number 7: 217; copy number 8: 33; copy number 9: 564; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 816 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:154,435,853–159,904,756, 73 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr3:172,828,736–198,123,232, 495 genes, copy number 9 (broad region; genes not listed).
- chr4:87,160,103–87,531,061, 13 genes, copy number 7: KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1.
- chr6:20,401,879–20,500,276, 5 genes, copy number 7: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA.
- chr9:25,676,389–25,844,585, 2 genes, copy number 10: TUSC1, LINC01241.
- chr13:26,557,683–29,595,688, 61 genes, copy number 7 (broad region; genes not listed).
- chr13:32,432,417–34,928,076, 32 genes, copy number 8 (within-gene range 5–8): N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1.
- chr20:31,257,664–34,698,790, 130 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr21:10,649,400–10,649,835, 1 gene, copy number 9: IGHV1OR21-1.
- chr22:16,503,304–16,509,475, 1 gene, copy number 8: CHEK2P4.
- chr22:18,527,802–18,530,573, 1 gene, copy number 7: TMEM191B.
- chr22:21,300,990–21,325,042, 2 genes, copy number 7 (within-gene range 3–7): FAM230H, AP000552.2.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
